Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7YJ, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7YJ-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

[REDACTED] is a y/o with medical hx significant for recent hospitalization at where a frontal brain lesion was identified. His initial symptoms were increased sleepiness, headache over his R eye, L side weakness, hearing loss all of which have been progressive.

MRI [REDACTED]: Patient is status post right frontal craniotomy with resection cavity in the right frontal lobe. There is irregular, nodular enhancement at the anterior and superior aspects of the resection cavity, with increased area of masslike enhancement more anteriorly in the right frontal lobe, extending to the margin of the right corpus callosum

Per TSS, prior surgery

- Now for

further resection.

NO Tx in between.

BCR

GROSS EXAMINATION:

A. "Brain tissue (AF1)", received fresh for frozen section. A 2.5 x 2.5 x 1.5 cm fragment of gray-tan tissue. Representative has been previously submitted as frozen section AF1. The frozen section remnant is submitted in A1. The remaining tissue is sectioned, representative is retained in formalin and the remainder is submitted in A2-3.

B. "Brain tissue", received fresh and placed in formalin. A 2.2 x 2.2 x 1.2 cm aggregate of two fragments of gray-tan tissue is received. Representative is retained in formalin and the remainder is sectioned and submitted in B1.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1-glioma, high grade

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a malignant astrocytic neoplasm characterized by cytologic pleomorphism and mitotic figures. No microvascular changes or pseudopalisading necrosis are seen.

ICD-O-3

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

ANAPLASTIC ASTROCYTOMA (WHO GRADE III)

B. "BRAIN TISSUE" (CRANIOTOMY):

ANAPLASTIC ASTROCYTOMA (WHO GRADE III)

Astrocytoma, grade III 9401/3
Site: [REDACTED], supratentorial NOS C71.0
Brain, frontal lobe C71.1
7/5 5/5/14

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (78% OF TUMOR CELLS EXHIBIT POLYSOMY)

[page 2 of 3]
EGFR - AMPLIFICATION (96% OF TUMOR CELLS EXHIBIT AMPLIFICATION)

CHROMOSOME 10 CENTROMERE - CENTROMERE LOSS (72% OF TUMOR CELLS EXHIBIT LOSS)

PTEN - ALLELIC LOSS (78% OF TUMOR CELLS EXHIBIT LOSS)

9p21 - LOSS (44% OF TUMOR CELLS EXHIBIT LOSS)

CHROMOSOME 9 CENTROMERE - CENTROMERE LOSS (36% OF TUMOR CELLS EXHIBIT LOSS)

4 OF 4 ABNORMAL MARKERS AND 9P21 EXHIBITS LOSS.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF PATIENTS WITH ANAPLASTIC ASTROCYTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH >2 MARKERS (P=0.037) EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

BOTH FISH AND IMMUNOHISTOCHEMISTRY FOR PTEN REVEAL SIMILAR FINDINGS INDICATIVE OF LOSS OF PTEN STATUS.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING ANAPLASTIC ASTROCYTOMA (WHO GRADE III; [REDACTED] BLOCK A2).

LEUCOCYTE COMMON ANTIGEN (LCA): 15% OF POSITIVE CELLS.

PROLIFERATION INDEX INTERPRETATION: HIGH PROLIFERATION INDEX (15% OF TUMOR CELLS EXHIBIT STAINING).

MGMT - POSITIVE (30% OF TUMOR CELLS)

EGFR wt - POSITIVE (3+ IN 90% OF TUMOR CELLS)

EGFR vIII - POSITIVE (2+ IN 10% OF TUMOR CELLS)

PTEN - LOSS (2+ IN 50% OF TUMOR CELLS)

S6 - POSITIVE (2+ IN 30% OF TUMOR CELLS)

AKT - POSITIVE (2+ IN 30% OF TUMOR CELLS)

MAPK - POSITIVE (2+ IN 40% OF TUMOR CELLS)

Please see Image Cytometry Report [REDACTED] For results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 3:

MGMT PROMOTER METHYLATION REAL TIME PCR ANALYSIS

Received [REDACTED] from

is a copy of an MGMT

[page 3 of 3]
Promoter Methylation Assay, obtained at the request of [REDACTED], on paraffin block [REDACTED] (requisition number [REDACTED]. The complete report from [REDACTED] is on file in the [REDACTED]

INTERPRETATION:

MGMT promoter methylation NOT identified.

Comment: The specimen is considered negative for MGMT promoter methylation when Methylation Index (MI) is less than 4. MI between 4 and 16 is considered as low level of methylation and should be interpreted with caution since the significance of low level methylation in gliomas is not well understood. MI greater than 16 is considered as methylated.

Reference: Vlassenbroeck I. Validation of real-time methylation-specific PCR to determine O6-methylguanine-DNA methyltransferase gene promoter methylation in gliomas. J. Mol. Diagn. 2008 10(4):332-337.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by: [REDACTED] Electronically signed: [REDACTED]
SURGICAL PATHOLOGY

Ordering MD:

Source: NCI Genomic Data Commons file 90250395-dde9-4af3-aa1f-9d53f356f4b1 (TCGA-E1-A7YJ.CF66C60F-354C-4BB5-9A07-8891FC553184.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).